CPTAC case C3N-02439 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/08f997e1-8249-4c31-ae8a-bd165f5ad29e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1960; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 57.2 years (20,891 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,174 days (3.2 years); Progression or recurrence: no; Days to last follow up: 1,174 days (3.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 10.5 cm (a second GDC size field records 8 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (4 entries)
- Days to follow up: 265 days; Disease response: Tumor Free.
- Days to follow up: 656 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 1,174 days (3.2 years); Disease response: Complete Response.
- Days to follow up: 1,174 days (3.2 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 87.54 kg; Height: 182.9 cm; BMI: 26.17.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 10; Cigarettes per day: 20; Tobacco smoking onset year: 1986; Tobacco smoking quit year: 1996; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 10.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02439-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 400 mg; Time between excision and freezing: 29 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02439-22: Section location: Upper and Middle pole; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-02439-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 406 mg; Time between excision and freezing: 33 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02439-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
